Somatic mutation profile of tumor specimen TCGA-CV-5443-01A (aliquot TCGA-CV-5443-01A-01D-1512-08) from TCGA case TCGA-CV-5443, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 63.8 years (23,287 days).
Specimen TCGA-CV-5443-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3b2bf0e8-be9c-420f-ab57-12ce9a4f45f1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-5443-11A (Solid Tissue Normal), aliquot TCGA-CV-5443-11A-01D-1512-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bed4569d-a6f4-42b1-bec0-adf8b0b9cf76

The open-access MAF lists 58 somatic variants for this specimen: 38 protein-altering or splice-affecting, 17 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 17, Nonsense Mutation 3, In Frame Del 2, Intron 1, Splice Site 1, 3'UTR 1, Splice Region 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 11/32 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAM20 | c.2101C>T p.P701S | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV56457247; called by muse, mutect2
- ASMT | c.771G>C p.W257C (on ENST00000381229; = p.W285C on NM_004043.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/209 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764047769, COSV101172511; called by muse, mutect2, varscan2
- BTBD10 | c.1300G>T p.D434Y | Missense Mutation (SNP) | VAF 53/150 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99533852; called by muse, mutect2, varscan2
- C4B | c.3667G>A p.E1223K | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.02); catalogued as COSV70313304; called by muse, mutect2, varscan2
- C7orf57 | c.189A>G p.I63M | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV100817320; called by muse, mutect2, varscan2
- CMTM5 | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.104); catalogued as rs200320289, COSV100198226, COSV59304968; called by muse, mutect2, varscan2
- CNTNAP5 | c.736G>T p.D246Y | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV101443950; called by muse, mutect2, varscan2
- ELFN2 | c.1847G>A p.R616H | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1332195647, COSV101297617; called by muse, mutect2, varscan2
- EPHB6 | c.1189G>A p.G397R | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101235994; called by muse, mutect2, varscan2
- FREM2 | c.3730A>T p.N1244Y | Missense Mutation (SNP) | VAF 68/253 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV99750257; called by muse, mutect2, varscan2
- GRIN1 | c.2442C>G p.A814= | Splice Region (SNP) | VAF 13/58 reads (22%) | catalogued as rs773708731, COSV100160378, COSV100160616; called by muse, mutect2, varscan2
- IFNGR1 | c.367C>T p.R123* | Nonsense Mutation (SNP) | VAF 7/138 reads (5%) | catalogued as COSV100880493; called by muse, mutect2
- KHDC1 | c.515-1G>T p.X172_splice (on ENST00000370384 / NM_001251874.2; = p.X99_splice on NM_030568.5) | Splice Site (SNP) | VAF 20/64 reads (31%) | catalogued as COSV100001945; called by muse, mutect2, varscan2
- KNDC1 | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV100465971; called by muse, mutect2, varscan2
- KRT13 | c.1207G>A p.A403T | Missense Mutation (SNP) | VAF 52/180 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.643); catalogued as rs1486562526, COSV99877472; called by muse, mutect2, varscan2
- LIPG | c.1268G>A p.W423* | Nonsense Mutation (SNP) | VAF 24/102 reads (24%) | catalogued as COSV99724672; called by muse, mutect2, varscan2
- LPCAT2 | c.928A>G p.M310V | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV100045190; called by muse, mutect2
- LRP1B | c.4982G>A p.R1661H | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as rs756168629, COSV67189242, COSV67241168; called by muse, mutect2, varscan2
- LRP6 | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs759106535, COSV53786736; called by muse, mutect2, varscan2
- MLF2 | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99180112; called by muse, mutect2, varscan2
- MPL | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs766638870, COSV65245280; called by muse, mutect2, varscan2
- NOTCH3 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.107); catalogued as rs755685473, COSV54647534; called by muse, mutect2
- OR2M3 | c.163C>A p.L55I | Missense Mutation (SNP) | VAF 124/416 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1017076010, COSV71758966; called by muse, varscan2
- OR51G1 | c.703G>T p.E235* | Nonsense Mutation (SNP) | VAF 31/104 reads (30%) | catalogued as rs1168694530, COSV100429362, COSV58969134; called by muse, mutect2, varscan2
- PAQR6 | c.713C>A p.A238D (on ENST00000292291 / NM_001272108.2; = p.A132D on NM_024897.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV99431531; called by muse, mutect2, varscan2
- PRPF6 | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV99412595; called by muse, mutect2, varscan2
- RCE1 | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1273316785, COSV58993528; called by muse, mutect2
- RELN | c.4411G>A p.G1471R | Missense Mutation (SNP) | VAF 9/151 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100634549; called by muse, mutect2
- SCYL1 | c.1445C>A p.P482Q | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99534475; called by muse, mutect2, varscan2
- SMARCAD1 | c.491C>T p.T164I | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV100759014, COSV62773856; called by muse, mutect2, varscan2
- SUPT6H | c.3116C>T p.T1039M | Missense Mutation (SNP) | VAF 59/248 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100112691; called by muse, mutect2, varscan2
- SYNE1 | c.3896C>T p.A1299V (on ENST00000367255 / NM_182961.4; = p.A1306V on NM_033071.3) | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.019); catalogued as rs1184329555, COSV99553822; called by muse, mutect2, varscan2
- UCHL3 | c.109A>G p.M37V | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as rs1314424539, COSV101111562; called by muse, mutect2, varscan2
- XRN1 | c.2476C>A p.P826T | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV99378714; called by muse, mutect2, varscan2
- MYO9A | c.5091_5093del p.E1697del | In Frame Del (DEL) | VAF 19/70 reads (27%) | called by pindel, varscan2
- SLC22A16 | c.1121_1129del p.Y374_F376del | In Frame Del (DEL) | VAF 11/91 reads (12%) | called by mutect2, pindel, varscan2
- SRCIN1 | c.3537del p.E1180Rfs*2 (on ENST00000621492; = p.E1146Rfs*2 on NM_025248.3) | Frame Shift Del (DEL) | VAF 3/28 reads (11%) | called by mutect2, pindel
- ADAMTS12 | c.4239C>T p.P1413= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as COSV61261646, COSV61268077; called by muse, mutect2, varscan2
- ADH4 | c.249C>A p.T83= | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as COSV99644352; called by muse, mutect2, varscan2
- AL121899.2 | c.771C>T p.S257= | Silent (SNP) | VAF 35/137 reads (26%) | catalogued as rs201594514, COSV67350013; called by muse, mutect2, varscan2
- ARMCX5 | c.807T>G p.P269= | Silent (SNP) | VAF 48/94 reads (51%) | catalogued as rs781215205, COSV99863507; called by muse, mutect2, varscan2
- DNAH9 | c.10302C>T p.D3434= | Silent (SNP) | VAF 40/137 reads (29%) | catalogued as rs762104226, COSV99307463; called by muse, mutect2, varscan2
- FAM193B | c.1893T>C p.G631= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV100286770, COSV61557907; called by muse, mutect2, varscan2
- H2BC21 | c.45C>G p.S15= | Silent (SNP) | VAF 40/117 reads (34%) | catalogued as COSV100480085; called by muse, mutect2, varscan2
- HR | c.3405C>T p.S1135= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV57194432; called by muse, mutect2, varscan2
- KLF10 | c.105G>A p.E35= | Silent (SNP) | VAF 54/195 reads (28%) | catalogued as COSV99574899; called by muse, mutect2, varscan2
- MAP1A | c.8085C>T p.L2695= | Silent (SNP) | VAF 29/130 reads (22%) | catalogued as rs202171638, COSV100288551; called by muse, mutect2, varscan2
- MS4A15 | c.87G>T p.L29= | Silent (SNP) | VAF 44/151 reads (29%) | catalogued as COSV100558935; called by muse, mutect2, varscan2
- PTCHD3 | c.531G>A p.P177= | Silent (SNP) | VAF 49/216 reads (23%) | catalogued as COSV71257092; called by muse, mutect2, varscan2
- RAI14 | c.2178C>T p.N726= | Silent (SNP) | VAF 25/60 reads (42%) | catalogued as COSV99464267; called by muse, mutect2, varscan2
- SMYD4 | c.399G>A p.Q133= | Silent (SNP) | VAF 56/220 reads (25%) | catalogued as COSV100563188; called by muse, mutect2
- TIE1 | c.1401G>A p.P467= | Silent (SNP) | VAF 29/107 reads (27%) | catalogued as rs199811076, COSV65251226; called by muse, mutect2, varscan2
- TMEM198 | c.411C>T p.S137= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as rs202000579, COSV99525387; called by muse, mutect2, varscan2
- UBE4A | c.3000G>A p.L1000= (on ENST00000252108 / NM_001204077.2; = p.L1007= on NM_004788.4) | Silent (SNP) | VAF 62/152 reads (41%) | catalogued as COSV99348498; called by muse, mutect2, varscan2
- BTN2A3P | n.1448-460A>G | Intron (SNP) | VAF 23/74 reads (31%) | called by muse, mutect2, varscan2
- DPP6 | c.*213C>T | 3'UTR (SNP) | VAF 4/19 reads (21%) | catalogued as rs1239710952, COSV59645853; called by muse, mutect2, varscan2
- MIR379 | n.28G>A | RNA (SNP) | VAF 4/40 reads (10%) | catalogued as rs115827677; called by mutect2, varscan2
